CGCI case BLGSP-71-19-99996 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/31b66c49-8e15-4aa5-a2fc-9a0c4387fe02

Demographics
Sex at birth: female.

Biospecimens (2 samples)
- Samples BLGSP-71-19-99996-17A.1, BLGSP-71-19-99996-17A.2 (2 with the same recorded description): Sample type: Lymphoid Normal; Tissue type: Normal; Specimen type: Lymphoid; Preservation method: Frozen.
